Somatic mutation profile of tumor specimen TARGET-20-PAEFGT-09A (aliquot TARGET-20-PAEFGT-09A-01D) from TARGET case TARGET-20-PAEFGT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,452 days).
Specimen TARGET-20-PAEFGT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e90322f6-d962-42f7-b850-71077691c953.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAEFGT-14A (Bone Marrow Normal), aliquot TARGET-20-PAEFGT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4d7cb9e-a485-4b5c-8fce-08bc5c1380bb

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.179C>A p.P60H (on ENST00000377970; = p.P75H on NM_002467.6) | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52367558, COSV52380145; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 22/48 reads (46%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- WT1 | c.1095_1102dup p.R368Lfs*72 | Frame Shift Ins (INS) | VAF 33/114 reads (29%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by mutect2, varscan2
